Gene-level copy-number profile of tumor specimen TCGA-97-8547-01A from TCGA case TCGA-97-8547, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 78.9 years (28,801 days).
Specimen TCGA-97-8547-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.98c94c57-1b01-4a12-9cf4-30161350d987.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-97-8547-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ecad3fa5-7e17-4c7a-90df-2da42ecdbfdc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 32; copy number 1: 14,815; copy number 2: 39,224; copy number 3: 3,366; copy number 4: 1,699; copy number 5: 483; copy number 6: 35; copy number 7: 86; copy number 8: 71; copy number 9: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-97-8547-01A-11D-2389-01): tumor purity 0.48, ploidy 1.88, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 32 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:94,166,258–94,200,902, 1 gene (within-gene range 0–1): MIRLET7A1HG.
- chr9:94,176,492–95,087,159, 28 genes (within-gene range 0–1): LINC02603, MIRLET7D, ZNF169, VDAC1P11, NUTM2F, AL691447.2, AL691447.1, PTMAP12, MFSD14B, YRDCP1, AL358232.2, AL358232.1, RNU6-669P, PCAT7, FBP2, FBP1, AL157936.1, AOPEP, MIR2278, AL807757.1, AL807757.2, AL353768.1, AL353768.2, MIR6081, MIR23B, MIR27B, MIR3074, MIR24-1.
- chr9:95,113,708–95,142,541, 3 genes: AL354893.2, AL354893.1, RNA5SP288.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 654 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:35,904,288–43,412,391, 136 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr5:74,721,206–87,499,340, 229 genes, copy number 5–8 (broad region; genes not listed).
- chr5:89,900,664–91,844,529, 28 genes, copy number 5: AC113167.1, MIR3660, LINC01339, AC099554.1, AC093510.2, CETN3, AC093510.1, MBLAC2, POLR3G, LYSMD3, ADGRV1, TMEM251P1, LUCAT1, AC074132.1, AC093281.1, AC093281.2, RNU4-90P, AC123595.1, AC123595.2, Metazoa_SRP, AC008799.1, AC008799.2, ARRDC3, ARRDC3-AS1, RAB5CP2, AC093298.2, PCBP2P3, AC093298.1.
- chr5:97,336,858–100,153,779, 49 genes, copy number 5–8: AC074133.1, YTHDF1P1, AC106748.1, LINC01340, MTCYBP40, AC112203.1, AC122697.1, LINC02234, AC008834.1, LINC01846, AC116347.1, PSME2P1, AC233964.1, KRT8P32, MRPS35P2, MTCO2P24, MTCO1P24, CTBP2P4, DDX18P4, RGMB, RGMB-AS1, AC008522.1, CSNK1A1P3, CHD1, RNU6-402P, LINC02062, Y_RNA, AC022121.1, AC114324.2, AC114324.1, GUSBP8, LINC02113, AC008837.1, AC008837.2, CRLF3P2, EEF1A1P20, Y_RNA, MTCYBP22, MTND6P22, MTND5P10, MTND4P35, MTND4LP5, MTND3P19, MTCO3P22, MTATP6P2, MTCO2P22, MTCO1P22, GUSBP7, RNU6-1119P.
- chr5:100,733,058–100,903,282, 3 genes, copy number 7: RN7SKP62, ST8SIA4, MIR548P.
- chr8:96,370,800–101,262,903, 102 genes, copy number 5–9 (broad region; genes not listed).
- chr8:105,546,089–106,060,524, 1 gene, copy number 7 (within-gene range 2–7): ZFPM2-AS1.
- chr8:105,737,280–108,083,642, 22 genes, copy number 7: RPL12P24, AC090802.1, Y_RNA, SLC16A14P1, AC027031.1, AC027031.2, OXR1, AC090579.1, TAGLN2P1, RNU7-84P, ABRA, AP003789.1, AP000428.2, HMGB1P46, AP000428.1, ANGPT1, AC091010.1, PGAM1P13, AC025508.1, RNA5SP275, RSPO2, NRBF2P4.
- chr8:123,497,889–126,008,930, 46 genes, copy number 5 (within-gene range 4–5): FBXO32, AC090193.1, RN7SKP155, AC135166.1, KLHL38, ANXA13, FAM91A1, FER1L6, AC090753.1, FER1L6-AS1, AC100871.2, FER1L6-AS2, AC100871.1, ARF1P3, AC090921.1, RNU6-756P, AC090192.2, AC090192.1, TMEM65, TRMT12, RNF139-AS1, RNF139, TATDN1, AC090198.1, MIR6844, NDUFB9, MTSS1, AC100858.2, MIR4662B, MIR4662A, LINC00964, MRS2P1, AC100858.1, AC100858.3, ZNF572, AC009908.1, SQLE, WASHC5, WASHC5-AS1, NSMCE2, RN7SL329P, AC084083.1, TRIB1, AC091114.1, AC016074.2, AC016074.1.
- chr8:128,634,199–130,655,712, 25 genes, copy number 6 (within-gene range 4–6): CCDC26, AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686, AC103718.1, MTRF1LP2, GSDMC, AC022973.5, CYRIB, AC022973.2, AC022973.1, AC022973.4, AC022973.3, AC131568.1, RNU7-181P, MIR5194, ASAP1, RNU6-1255P, ASAP1-IT2, AC103725.1, AC009682.1, AC139019.1, AC090987.1.
- chr8:135,457,456–137,645,564, 9 genes, copy number 7 (within-gene range 3–7): KHDRBS3, MAPRE1P1, RNU1-35P, LINC02055, AC103955.1, AC023781.1, RNU6-144P, ZYXP1, AC105213.1.
- chr8:139,911,238–140,100,543, 4 genes, copy number 7: AC021744.1, C8orf17, AC040978.1, PEG13.

Autosomal genes at a single copy (total copy number 1): 14,231. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
